Somatic mutation profile of tumor specimen TCGA-D6-6516-01A (aliquot TCGA-D6-6516-01A-11D-1870-08) from TCGA case TCGA-D6-6516, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.1 years (25,242 days).
Specimen TCGA-D6-6516-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f8ae92f-ebfc-4d19-8f08-0d67fd75829b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6516-10A (Blood Derived Normal), aliquot TCGA-D6-6516-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/487595ba-2310-450c-ad2e-1aaebe16d277

The open-access MAF lists 2,171 somatic variants for this specimen: 1,418 protein-altering or splice-affecting, 702 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,303, Silent 702, Nonsense Mutation 74, Splice Site 21, Intron 19, RNA 15, Splice Region 11, Frame Shift Del 7, 5'Flank 6, 3'UTR 5, 3'Flank 5, Frame Shift Ins 1.

Variants (750 of 2,171; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CLRN1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs111033434, COSV100184513; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CYP7B1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 58/310 reads (19%) | catalogued as rs886041525, COSV100042075, COSV59592380; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.888G>A p.W296* (on ENST00000377211 / NM_001201397.1; = p.W206* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 24/166 reads (14%) | catalogued as rs876657688, COSV100526741; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EXTL3 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554294508, COSV99594072; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778700089, CM094649, COSV100257417; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LPA | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 57/298 reads (19%) | catalogued as rs121912503, COSV60296281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NDUFAF1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs387906958, CM117654, COSV99531479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PDYN | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201486601, CM107860, COSV54101259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WWOX | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 40/131 reads (31%) | catalogued as rs756762196, COSV101283072; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1322C>G p.S441* | Nonsense Mutation (SNP) | VAF 24/136 reads (18%) | catalogued as COSV99771495; called by muse, mutect2, varscan2
- ABAT | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 125/368 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51624402; called by muse, mutect2, varscan2
- ABCA13 | c.13271C>T p.T4424I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as COSV101291363; called by muse, mutect2, varscan2
- ABCA13 | c.14500C>T p.P4834S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs1398457581, COSV68949280, COSV99066287; called by mutect2, varscan2
- ABCA4 | c.4676G>A p.G1559E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV100933144; called by muse, mutect2, varscan2
- ABCA6 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs918951671, COSV52644197; called by muse, mutect2, varscan2
- ABCA7 | c.2404G>A p.G802S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV54028067; called by muse, mutect2, varscan2
- ABCB11 | c.2075G>A p.R692K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.293); catalogued as COSV99791528, COSV99792348; called by muse, mutect2, varscan2
- ABCC10 | c.2018C>T p.P673L (on ENST00000372530 / NM_001198934.2; = p.P645L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1336089750, COSV99767391; called by muse, mutect2, varscan2
- ABCC11 | c.3224C>T p.S1075F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62325826; called by muse, mutect2, varscan2
- ABCC2 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as rs774163715, COSV64971481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.3896C>T p.P1299L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs794728957, COSV99685931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.2560G>A p.G854R | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1441506948, COSV99685935; called by muse, mutect2, varscan2
- ABCD2 | c.1797G>A p.W599* | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | catalogued as rs1011018570; called by muse, mutect2
- ABCF1 | c.1850C>T p.P617L (on ENST00000326195 / NM_001025091.2; = p.P579L on NM_001090.3) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1255518429, COSV100400875; called by muse, mutect2, varscan2
- ABCG1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100494265; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs758144632, COSV100044979; called by muse, mutect2, varscan2
- ACAD10 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV100564268; called by muse, mutect2, varscan2
- ACAP1 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as rs1474050169, COSV99341737; called by muse, mutect2, varscan2
- ACE | c.3712C>T p.P1238S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1568049498, COSV99327208; called by muse, mutect2, varscan2
- ACMSD | c.977C>A p.A326E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99299158; called by muse, mutect2, varscan2
- ACOXL | c.1633-2A>C p.X545_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as rs752300404, COSV100929854; called by muse, mutect2, varscan2
- ACP6 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782479679, COSV65078206; called by muse, mutect2, varscan2
- ACSM2A | c.295G>A p.G99R (on ENST00000219054; = p.G20R on NM_001308169.2) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV54582700; called by muse, mutect2, varscan2
- ACTG1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as COSV100111965; called by muse, varscan2
- ACTG1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as COSV100111967; called by muse, varscan2
- ACTL7B | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV65927463; called by muse, mutect2, varscan2
- ACTL8 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64862748; called by muse, mutect2, varscan2
- ACTN3 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100074326; called by muse, mutect2, varscan2
- ACTN3 | c.2690G>A p.G897E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074327; called by muse, mutect2, varscan2
- ACTRT1 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 272/347 reads (78%) | catalogued as rs767426435, COSV100947568, COSV64419153; called by muse, mutect2, varscan2
- ADAM33 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.207); catalogued as COSV100597931; called by muse, mutect2, varscan2
- ADAM7 | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs911395416, COSV51535792; called by muse, mutect2, varscan2
- ADAM7 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51539799; called by muse, mutect2, varscan2
- ADAMTS12 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61272347; called by muse, mutect2, varscan2
- ADAMTS13 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs139951127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS17 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1239206067, COSV99170794; called by muse, mutect2, varscan2
- ADAMTS4 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV100917471; called by muse, mutect2, varscan2
- ADAMTS9 | c.3850C>T p.P1284S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99899597; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99079255, COSV99443281; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV99719254; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV55008355, COSV99647453; called by muse, mutect2, varscan2
- ADCY1 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV99812185; called by muse, mutect2, varscan2
- ADCY8 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99652659; called by muse, mutect2, varscan2
- ADGRA1 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.292); catalogued as COSV101192706; called by muse, mutect2, varscan2
- ADGRF1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.952); catalogued as rs754302413, COSV100982618; called by muse, mutect2, varscan2
- ADGRL2 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV54656616; called by muse, mutect2, varscan2
- ADGRV1 | c.15737G>A p.R5246Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs772037044, COSV67991803; called by muse, mutect2, varscan2
- AFAP1L1 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs369805051; called by muse, mutect2, varscan2
- AFF1 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.077); catalogued as COSV100320724, COSV57123022; called by muse, mutect2, varscan2
- AFTPH | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99480843; called by muse, mutect2, varscan2
- AGFG1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100028879; called by muse, mutect2, varscan2
- AHI1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99662947; called by muse, mutect2, varscan2
- AHNAK | c.13693C>T p.P4565S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs377332726, COSV99947883; called by muse, mutect2, varscan2
- AHNAK | c.10622C>T p.P3541L | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99947891; called by muse, mutect2, varscan2
- AHNAK | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 74/457 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57214974; called by muse, mutect2, varscan2
- AHNAK2 | c.7256C>T p.P2419L | Missense Mutation (SNP) | VAF 61/358 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100317812, COSV60924878; called by muse, mutect2, varscan2
- AHRR | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100327451; called by muse, mutect2, varscan2
- AIMP2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.505); catalogued as rs372238513, COSV52239883; called by muse, mutect2, varscan2
- AIRE | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV99381200; called by muse, mutect2
- AK7 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV99967322; called by muse, mutect2, varscan2
- AKAP1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV100028023; called by muse, mutect2, varscan2
- AKAP6 | c.6523C>T p.P2175S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV99801492; called by muse, mutect2, varscan2
- AKAP9 | c.3307A>T p.K1103* | Nonsense Mutation (SNP) | VAF 30/95 reads (32%) | catalogued as COSV100662512; called by muse, mutect2, varscan2
- AKNA | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs959521665, COSV99800511; called by muse, mutect2, varscan2
- AKR7A2 | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs961157478, COSV52517133; called by muse, mutect2, varscan2
- AL592490.1 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV101308218, COSV69425214; called by muse, mutect2, varscan2
- ALB | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV99891604; called by muse, mutect2, varscan2
- ALDH1B1 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV100890951; called by muse, mutect2, varscan2
- ALDH3B2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100824061; called by muse, mutect2, varscan2
- ALMS1 | c.6923C>T p.S2308F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs775594311, COSV100042712; called by muse, varscan2
- ALMS1 | c.9397C>T p.P3133S | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100042715; called by muse, mutect2, varscan2
- ALPK2 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100864455; called by muse, mutect2, varscan2
- AMER3 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as rs779930643, COSV100366643; called by muse, mutect2, varscan2
- ANGEL1 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV51874117, COSV99200425; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4507C>T p.P1503S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51844873; called by muse, mutect2
- ANKIB1 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as rs1244702186, COSV99729228, COSV99730053; called by muse, mutect2, varscan2
- ANKRD11 | c.7483C>T p.P2495S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56363945, COSV99969657; called by muse, mutect2, varscan2
- ANKRD12 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100041478; called by muse, mutect2, varscan2
- ANKRD26 | c.2923A>T p.N975Y | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101063263; called by muse, mutect2, varscan2
- ANKRD44 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99985190; called by muse, mutect2, varscan2
- ANKRD49 | c.239G>A p.W80* | Nonsense Mutation (SNP) | VAF 28/148 reads (19%) | catalogued as rs1303258857, COSV100119759; called by muse, mutect2, varscan2
- ANKRD50 | c.4283C>T p.P1428L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101538983; called by muse, mutect2, varscan2
- ANKRD50 | c.4282C>T p.P1428S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV72385527, COSV72386391; called by muse, mutect2, varscan2
- ANKRD52 | c.2737C>T p.R913* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV57283964; called by muse, mutect2, varscan2
- ANKS1B | c.2583del p.H862Tfs*15 (on ENST00000547776 / NM_152788.4; = p.H88Tfs*15 on NM_020140.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV100228276; called by mutect2, pindel, varscan2
- ANO5 | c.2308A>C p.T770P | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV100201931; called by muse, mutect2, varscan2
- AOAH | c.1134-1G>A p.X378_splice | Splice Site (SNP) | VAF 25/135 reads (19%) | catalogued as COSV99333001; called by muse, mutect2, varscan2
- AOC2 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV53824523; called by muse, mutect2, varscan2
- AOPEP | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99468647; called by muse, mutect2, varscan2
- AP1G1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs768433108, COSV55486253, COSV55496649; called by muse, mutect2, varscan2
- AP3B2 | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.068); catalogued as COSV99916593; called by muse, mutect2, varscan2
- APBA3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV100349691; called by muse, mutect2, varscan2
- APMAP | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV99468672; called by muse, mutect2
- APOB | c.4514G>T p.C1505F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99266053; called by muse, mutect2, varscan2
- APPBP2 | c.858A>T p.K286N | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV99319723; called by muse, mutect2, varscan2
- ARAP3 | c.1837C>T p.H613Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99499821; called by muse, mutect2, varscan2
- ARFGEF2 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64212333; called by muse, mutect2, varscan2
- ARHGAP30 | c.2689G>A p.E897K (on ENST00000368013 / NM_001025598.2; = p.E686K on NM_181720.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); catalogued as COSV63517450; called by muse, mutect2, varscan2
- ARHGAP36 | c.365T>G p.V122G | Missense Mutation (SNP) | VAF 131/219 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99357791; called by muse, mutect2, varscan2
- ARHGAP44 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV99310886; called by muse, mutect2, varscan2
- ARHGEF1 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs200700112, COSV61526576; called by muse, mutect2, varscan2
- ARHGEF11 | c.3851C>T p.S1284F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100168677; called by muse, mutect2, varscan2
- ARHGEF12 | c.3431T>A p.L1144* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100754973; called by muse, mutect2, varscan2
- ARHGEF17 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs373169732; called by muse, mutect2, varscan2
- ARHGEF17 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1421151251, COSV99735830; called by muse, mutect2, varscan2
- ARID1A | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.023); catalogued as COSV61380509; called by muse, mutect2, varscan2
- ARID1A | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.397); catalogued as rs1311674614, COSV100252002, COSV61376016; called by muse, mutect2, varscan2
- ARID1B | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV51652830, COSV51676027; called by muse, mutect2, varscan2
- ARID4A | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100794344; called by muse, mutect2, varscan2
- ARID5B | c.2384C>T p.P795L | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99689831; called by muse, mutect2, varscan2
- ARL9 | c.746C>T p.T249I (on ENST00000640821 / NM_001363794.2; = p.T107I on NM_206919.2) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100781277; called by muse, mutect2, varscan2
- ARMT1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.732); catalogued as COSV100939807; called by muse, mutect2, varscan2
- ARRB2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765964965, COSV52619205; called by muse, mutect2, varscan2
- ASB8 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV100402526; called by muse, mutect2, varscan2
- ASPH | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101063962, COSV65247437; called by muse, mutect2, varscan2
- ASPHD2 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1451332810, COSV99313405; called by muse, mutect2, varscan2
- ASS1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100752676; called by muse, mutect2, varscan2
- ASTL | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs565777679, COSV100668368; called by muse, mutect2, varscan2
- ASTN1 | c.2793G>A p.M931I | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as rs770373511, COSV100707080; called by muse, mutect2, varscan2
- ASTN1 | c.1716G>A p.M572I | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV99922030; called by muse, mutect2, varscan2
- ASXL2 | c.252G>A p.K84= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99711323; called by muse, mutect2, varscan2
- ASXL3 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV99325210; called by muse, mutect2, varscan2
- ATF2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs768206343, COSV51368070; called by muse, mutect2, varscan2
- ATP10A | c.3947G>A p.R1316K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100791314; called by muse, mutect2, varscan2
- ATP10A | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV100791315; called by muse, mutect2, varscan2
- ATP10B | c.3071C>T p.S1024F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100515162; called by muse, mutect2, varscan2
- ATP12A | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99517787; called by muse, mutect2, varscan2
- ATP13A4 | c.1899T>A p.F633L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.317); catalogued as COSV99794644; called by muse, mutect2
- ATP1B4 | c.928C>T p.P310S (on ENST00000218008 / NM_001142447.3; = p.P306S on NM_012069.5) | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200756053, COSV54312706, COSV99486395; called by muse, mutect2, varscan2
- ATP2B3 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV54841869; called by muse, mutect2, varscan2
- ATP8A2 | c.2863G>A p.G955S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.982); catalogued as COSV99682363; called by muse, mutect2, varscan2
- ATRX | c.4717G>A p.D1573N | Missense Mutation (SNP) | VAF 226/294 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100970897; called by muse, mutect2, varscan2
- ATXN2 | c.2006C>T p.S669L (on ENST00000550104; = p.S509L on NM_002973.4) | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs774827848, COSV66484550; called by muse, mutect2, varscan2
- ATXN7 | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99894588; called by muse, mutect2, varscan2
- AUH | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs776409546, COSV57861320; called by muse, mutect2, varscan2
- AXIN1 | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as rs774921991, COSV51990096; called by muse, mutect2, varscan2
- AXIN1 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99249908; called by muse, mutect2, varscan2
- B4GALNT1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247184; called by muse, mutect2, varscan2
- B9D1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs764681399, COSV52070338; called by muse, mutect2, varscan2
- BAZ2A | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs1371320673, COSV99466513; called by muse, mutect2, varscan2
- BAZ2B | c.4790C>T p.P1597L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV100600719; called by muse, mutect2, varscan2
- BCAN | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV61258391; called by muse, mutect2, varscan2
- BCHE | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100012635; called by muse, mutect2, varscan2
- BCL2 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100384674; called by muse, mutect2, varscan2
- BEND3 | c.2105C>T p.P702L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100944623; called by muse, mutect2, varscan2
- BLVRA | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99646017; called by muse, mutect2, varscan2
- BNC2 | c.698G>A p.W233* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV101033482; called by muse, mutect2, varscan2
- BRPF3 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV60207751; called by muse, mutect2, varscan2
- BTBD2 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99724796; called by muse, mutect2, varscan2
- BUD13 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99496521; called by muse, mutect2, varscan2
- C11orf65 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV101262842; called by muse, mutect2, varscan2
- C14orf93 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.587); catalogued as COSV100136738; called by muse, mutect2, varscan2
- C15orf39 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs1399236246, COSV100641369; called by muse, mutect2, varscan2
- C16orf78 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546860439, COSV54555346; called by muse, mutect2, varscan2
- C19orf18 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); catalogued as rs35437132; called by muse, mutect2, varscan2
- C19orf44 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55610508; called by muse, varscan2
- C1QTNF9B | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1226647528, COSV101158588; called by muse, mutect2, varscan2
- C1S | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1555161766, COSV100196605; called by muse, mutect2, varscan2
- C1orf146 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV64860557; called by muse, mutect2, varscan2
- C1orf198 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 19/101 reads (19%) | catalogued as COSV64175822; called by muse, mutect2, varscan2
- C1orf74 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99161785; called by muse, mutect2, varscan2
- C2CD3 | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV100486867; called by muse, mutect2, varscan2
- C5 | c.3478C>T p.P1160S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV99798070; called by muse, mutect2, varscan2
- C6 | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99667202; called by muse, mutect2, varscan2
- C6 | c.1458G>T p.E486D | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV54710578, COSV99667205; called by muse, mutect2, varscan2
- C6orf15 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV52537412; called by muse, mutect2, varscan2
- C8orf34 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1206976780, COSV100298451; called by muse, mutect2
- C9orf135 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV101019883; called by muse, mutect2, varscan2
- CA4 | c.509T>G p.V170G | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99958412; called by muse, mutect2, varscan2
- CA8 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100527003; called by muse, mutect2, varscan2
- CACNA1E | c.5084G>A p.G1695D | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100703150; called by muse, mutect2, varscan2
- CACNA1G | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.174); catalogued as rs1468000824, COSV100661942; called by muse, mutect2, varscan2
- CACNA1I | c.2846C>T p.S949F | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV60817784; called by muse, mutect2, varscan2
- CALN1 | c.264G>A p.G88= (on ENST00000329008 / NM_001017440.3; = p.G130= on NM_031468.4) | Splice Region (SNP) | VAF 13/120 reads (11%) | catalogued as COSV100207436; called by muse, mutect2, varscan2
- CARD10 | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV52660487; called by muse, mutect2, varscan2
- CARMIL1 | c.2423C>T p.T808I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100278076; called by muse, mutect2, varscan2
- CARMIL2 | c.3812C>T p.A1271V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99537762; called by muse, mutect2, varscan2
- CASP5 | c.182-1G>A p.X61_splice | Splice Site (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99507691; called by muse, mutect2, varscan2
- CASP8AP2 | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99387122; called by muse, mutect2, varscan2
- CASR | c.2854G>A p.E952K (on ENST00000490131; = p.E1029K on NM_000388.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV56141462; called by muse, mutect2, varscan2
- CAT | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573270; called by muse, mutect2, varscan2
- CATSPERG | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV99286595; called by muse, mutect2, varscan2
- CATSPERG | c.2848G>A p.V950M | Missense Mutation (SNP) | VAF 74/358 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99286597; called by muse, mutect2, varscan2
- CBX7 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99334089; called by muse, mutect2, varscan2
- CBY2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs780972113, COSV100137645; called by muse, mutect2, varscan2
- CC2D2A | c.3498T>A p.D1166E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101052799; called by muse, mutect2
- CCDC113 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.317); catalogued as rs1400547103, COSV99540978; called by muse, mutect2, varscan2
- CCDC141 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV99836932; called by muse, mutect2, varscan2
- CCDC180 | c.3956G>A p.G1319E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100826863; called by muse, mutect2, varscan2
- CCDC181 | c.728A>T p.N243I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.387); catalogued as COSV100890336; called by muse, mutect2, varscan2
- CCDC33 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58358179; called by muse, mutect2, varscan2
- CCDC60 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs764208425, COSV59540294; called by muse, mutect2, varscan2
- CCDC85A | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs1318665672, COSV101339478; called by muse, mutect2, varscan2
- CCDC85A | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.944); catalogued as rs767454240, COSV68153358; called by muse, mutect2, varscan2
- CCDC88C | c.3548C>T p.A1183V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV101105773; called by muse, mutect2, varscan2
- CCDC92 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99435615; called by muse, mutect2, varscan2
- CCDC9B | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV101233526; called by muse, mutect2, varscan2
- CCKAR | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55161779, COSV99810327; called by muse, mutect2, varscan2
- CCNL2 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV101275690; called by muse, varscan2
- CCP110 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV101195290; called by muse, mutect2, varscan2
- CCR3 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100656562, COSV100656875; called by muse, mutect2, varscan2
- CCR4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs752494781, COSV58384563; called by muse, mutect2, varscan2
- CD163 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV100775884, COSV63129661; called by muse, mutect2, varscan2
- CD163L1 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1044594735, COSV100550172; called by muse, mutect2, varscan2
- CD248 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100256624; called by muse, mutect2, varscan2
- CD40 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs756898850, COSV100953848; called by muse, mutect2
- CD44 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV53528494; called by muse, mutect2
- CD6 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV100533062; called by muse, mutect2, varscan2
- CD74 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99153875; called by muse, mutect2, varscan2
- CD86 | c.847G>A p.G283R (on ENST00000330540 / NM_175862.5; = p.G277R on NM_006889.4) | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV100054009; called by muse, mutect2, varscan2
- CD96 | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99343023; called by muse, mutect2, varscan2
- CDH8 | c.678A>T p.K226N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100182068; called by muse, mutect2, varscan2
- CDK13 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1230386094, COSV99475655; called by muse, mutect2, varscan2
- CDK13 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99475657; called by muse, mutect2
- CDKL4 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs1472889579, COSV101115334; called by muse, mutect2, varscan2
- CDYL2 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101629583; called by muse, mutect2, varscan2
- CEACAM16 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV101312709; called by muse, mutect2, varscan2
- CEACAM19 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100715379, COSV100715467; called by muse, mutect2, varscan2
- CECR2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1313171620, COSV99378192; called by muse, mutect2, varscan2
- CELA2B | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs199863613, COSV101025818; called by muse, mutect2, varscan2
- CELF1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100136983; called by muse, mutect2, varscan2
- CELSR2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV54780386, COSV99604056; called by muse, mutect2, varscan2
- CELSR3 | c.8093G>A p.G2698E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV99373777; called by muse, mutect2, varscan2
- CELSR3 | c.7010C>T p.P2337L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV50844026; called by muse, mutect2, varscan2
- CEP152 | c.4619C>T p.P1540L (on ENST00000380950 / NM_001194998.2; = p.P1484L on NM_014985.4) | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV100358878; called by muse, mutect2, varscan2
- CEP290 | c.6437G>A p.R2146K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100468914; called by muse, mutect2
- CFAP65 | c.2164C>T p.P722S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.273); catalogued as COSV100445267; called by muse, mutect2, varscan2
- CFHR1 | c.401G>A p.W134* | Nonsense Mutation (SNP) | VAF 33/115 reads (29%) | catalogued as rs1296094673, COSV57627849; called by muse, mutect2, varscan2
- CFP | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99901494; called by muse, mutect2, varscan2
- CHD2 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV101245412; called by muse, mutect2, varscan2
- CHEK2 | c.1724C>T p.T575I (on ENST00000382580 / NM_001005735.2; = p.T532I on NM_007194.4) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV100101863, COSV60428157; called by muse, mutect2, varscan2
- CHFR | c.1684-1G>T p.X562_splice (on ENST00000432561 / NM_001161345.1; = p.X521_splice on NM_018223.2) | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV57174194; called by muse, mutect2, varscan2
- CHGB | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV100972978; called by muse, mutect2, varscan2
- CHI3L1 | c.894G>A p.E298= | Splice Region (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99704009; called by muse, mutect2, varscan2
- CHN2 | c.914-1G>A p.X305_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99765157, COSV99765263; called by muse, mutect2, varscan2
- CHPF2 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.199); catalogued as COSV99223134; called by muse, mutect2, varscan2
- CHRNA4 | c.1773G>A p.W591* | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | catalogued as rs267606047, COSV100937397; called by muse, mutect2, varscan2
- CHRNB3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1361729767, COSV51497330, COSV99251251; called by muse, mutect2, varscan2
- CHST8 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.36); catalogued as rs1328572462, COSV52864831; called by muse, mutect2, varscan2
- CHUK | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100957154; called by muse, mutect2, varscan2
- CIITA | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100162078; called by muse, mutect2, varscan2
- CILK1 | c.947A>T p.Y316F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100607782; called by muse, mutect2, varscan2
- CLCA1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753995315, COSV52324938, COSV52328286; called by muse, mutect2, varscan2
- CLCN2 | c.2669C>G p.P890R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs773777498, COSV99658662; called by mutect2, varscan2
- CLK2 | c.796C>T p.Q266* (on ENST00000368361 / NM_001294339.2; = p.Q265* on NM_003993.4) | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100226766; called by muse, mutect2, varscan2
- CLPTM1 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.57); catalogued as rs1400793332, COSV100493802; called by muse, mutect2, varscan2
- CLTCL1 | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.552); catalogued as COSV99595255; called by muse, mutect2, varscan2
- CMIP | c.1442C>T p.P481L (on ENST00000537098 / NM_198390.2; = p.P387L on NM_030629.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs866072283, COSV101220925; called by muse, mutect2, varscan2
- CNOT4 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV59659594; called by muse, mutect2, varscan2
- CNTN3 | c.800T>G p.L267R | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99724802; called by muse, mutect2, varscan2
- CNTNAP2 | c.961T>A p.F321I | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62208497, COSV62211017; called by muse, mutect2, varscan2
- CNTNAP2 | c.3898G>A p.G1300R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.974); catalogued as rs747201477, COSV100667116; called by muse, mutect2, varscan2
- CNTNAP4 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV100271816; called by muse, mutect2, varscan2
- CNTROB | c.1735-1G>A p.X579_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100972699; called by muse, mutect2, varscan2
- CNTROB | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs1209656627, COSV100972700; called by muse, mutect2, varscan2
- COG5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99772327; called by muse, mutect2, varscan2
- COG5 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1279772707, COSV99772329; called by muse, mutect2, varscan2
- COL11A1 | c.3200C>T p.T1067I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100616958; called by muse, mutect2
- COL11A1 | c.3134G>A p.G1045E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616959; called by muse, varscan2
- COL11A1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62184605; called by muse, mutect2, varscan2
- COL11A2 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as COSV100554138; called by muse, mutect2
- COL12A1 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV100486103; called by muse, mutect2, varscan2
- COL14A1 | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV99919522; called by muse, mutect2, varscan2
- COL17A1 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138894227; called by muse, mutect2, varscan2
- COL19A1 | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506485, COSV59589417; called by muse, mutect2, varscan2
- COL20A1 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1298335670, COSV100490702; called by muse, mutect2, varscan2
- COL24A1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as rs367868461; called by muse, mutect2, varscan2
- COL27A1 | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100621043; called by muse, mutect2, varscan2
- COL28A1 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV101258685; called by muse, mutect2, varscan2
- COL4A3 | c.4288G>A p.G1430R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV101170323; called by muse, mutect2, varscan2
- COL5A1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV100880048; called by muse, mutect2, varscan2
- COL5A1 | c.3779C>T p.S1260F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100880049; called by muse, mutect2
- COL5A3 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99319045; called by muse, mutect2, varscan2
- COL6A6 | c.4471G>A p.G1491R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100650341; called by muse, mutect2, varscan2
- COL8A2 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV57441673; called by muse, mutect2, varscan2
- COLEC11 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as COSV99363336; called by mutect2, varscan2
- COPS2 | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as COSV54648144; called by muse, mutect2, varscan2
- CPAMD8 | c.1369C>T p.P457S (on ENST00000651564; = p.P410S on NM_015692.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52237352; called by muse, mutect2, varscan2
- CPD | c.1288C>T p.L430F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as rs373237520; called by muse, mutect2, varscan2
- CPEB1 | c.608C>T p.P203L (on ENST00000617958; = p.P143L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.372); catalogued as rs897294113, COSV99917762; called by muse, mutect2, varscan2
- CPED1 | c.2045G>A p.G682D | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV100120893; called by muse, mutect2, varscan2
- CPLX4 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100231407; called by muse, mutect2, varscan2
- CPM | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200496918, COSV100615112; called by muse, mutect2, varscan2
- CPQ | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV55161458; called by muse, mutect2
- CPS1 | c.2872C>G p.L958V | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51810433, COSV99242654; called by muse, mutect2
- CPXM1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV101013753, COSV66045935; called by muse, mutect2, varscan2
- CR2 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889660, COSV65508724; called by muse, mutect2, varscan2
- CRACD | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as COSV99949433; called by muse, mutect2
- CRB1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs760083289, COSV66340049; called by muse, mutect2, varscan2
- CRB1 | c.3496C>G p.P1166A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.433); catalogued as COSV100957923; called by muse, mutect2, varscan2
- CRB1 | c.3497C>T p.P1166L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV66333601; called by muse, mutect2, varscan2
- CRELD1 | c.690G>T p.L230F | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV99926567; called by muse, mutect2, varscan2
- CRELD2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100078093, COSV58207981; called by muse, mutect2, varscan2
- CRHBP | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV57187926, COSV57188399; called by muse, mutect2, varscan2
- CSF2RB | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99453978; called by muse, mutect2, varscan2
- CSMD1 | c.8752C>T p.P2918S (on ENST00000520002; = p.P2917S on NM_033225.6) | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.158); catalogued as COSV59349442; called by muse, mutect2, varscan2
- CSMD1 | c.5765C>T p.P1922L (on ENST00000520002; = p.P1921L on NM_033225.6) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1202357181, COSV59291762, COSV59301442; called by muse, mutect2, varscan2
- CSMD2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as COSV53956681, COSV99593440; called by muse, mutect2, varscan2
- CSMD3 | c.9181A>G p.T3061A (on ENST00000297405 / NM_001363185.1; = p.T2892A on NM_052900.3) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99836664; called by muse, mutect2, varscan2
- CTDSP2 | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101143015, COSV66079941; called by muse, mutect2, varscan2
- CTNND2 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1028155744, COSV58882446, COSV58935372; called by muse, mutect2, varscan2
- CTSE | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.98); PolyPhen benign (0.012); catalogued as COSV100733667; called by muse, mutect2, varscan2
- CUX2 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99919886; called by muse, mutect2, varscan2
- CUX2 | c.3734G>A p.G1245E | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV99919888; called by muse, mutect2, varscan2
- CXorf58 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs753173434, COSV64858200; called by muse, mutect2, varscan2
- CYP19A1 | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 34/64 reads (53%) | catalogued as rs1335348345, COSV53063855; called by muse, mutect2, varscan2
- CYP2F1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs1205899633, COSV100462767; called by muse, mutect2, varscan2
- CYP3A43 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV99733261; called by muse, mutect2, varscan2
- CYP4A22 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595036; called by muse, mutect2, varscan2
- DAAM2 | c.2820G>T p.K940N (on ENST00000274867 / NM_001201427.2; = p.K939N on NM_015345.3) | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99225915; called by muse, mutect2, varscan2
- DAPK1 | c.2046G>C p.Q682H | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100802034; called by muse, mutect2, varscan2
- DAPK3 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100009718; called by muse, mutect2, varscan2
- DARS1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99927610; called by muse, mutect2
- DBT | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.169); catalogued as COSV100923522; called by muse, mutect2, varscan2
- DCAF15 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99586198; called by muse, mutect2, varscan2
- DCAF5 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV100432570; called by muse, mutect2, varscan2
- DCT | c.748G>T p.G250W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100986237; called by mutect2, varscan2
- DDC | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV63565580, COSV63568253; called by muse, mutect2, varscan2
- DDX4 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100737576; called by muse, mutect2, varscan2
- DEFB115 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs866556239, COSV68723000; called by muse, mutect2, varscan2
- DEFB127 | c.263T>G p.I88R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV101213843; called by muse, mutect2, varscan2
- DGKH | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99818965; called by muse, mutect2
- DGKI | c.2479C>G p.R827G | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs150062419, COSV99935086; called by muse, mutect2, varscan2
- DHX37 | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439294; called by muse, mutect2, varscan2
- DHX37 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100439353, COSV58132902; called by muse, mutect2, varscan2
- DIAPH1 | c.2335C>T p.L779F | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV99526702; called by muse, mutect2, varscan2
- DIAPH2 | c.2581C>T p.L861F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100233276; called by muse, mutect2, varscan2
- DIDO1 | c.5726C>T p.P1909L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99826130; called by muse, mutect2, varscan2
- DIDO1 | c.5725C>T p.P1909S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs933965423, COSV99826134; called by muse, mutect2, varscan2
- DLG5 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100967556; called by muse, mutect2, varscan2
- DLK1 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV100375262, COSV100375308; called by muse, mutect2, varscan2
- DLL1 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100816102; called by muse, mutect2, varscan2
- DMD | c.6184G>T p.A2062S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV100820174; called by muse, mutect2, varscan2
- DMGDH | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as COSV54863097, COSV99669114; called by muse, mutect2, varscan2
- DMTF1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs769167320, COSV100487412; called by muse, mutect2, varscan2
- DNAH10 | c.1537C>T p.R513W (on ENST00000409039; = p.R452W on NM_207437.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs762207670, COSV68999026; called by muse, mutect2, varscan2
- DNAH2 | c.10475C>T p.P3492L | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209394; called by muse, mutect2, varscan2
- DNAH5 | c.12339G>A p.M4113I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99450635; called by muse, mutect2, varscan2
- DNAH5 | c.10058C>T p.S3353F | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs867290467, COSV54227813; called by muse, mutect2, varscan2
- DNAH8 | c.2930C>T p.A977V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs1060501472, COSV100545777; ClinVar: uncertain significance; called by muse, mutect2
- DNAI2 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100209828; called by muse, mutect2, varscan2
- DNAJC22 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101222547; called by muse, mutect2, varscan2
- DNAJC3 | c.1064T>G p.M355R | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100953391; called by muse, mutect2, varscan2
- DNHD1 | c.12941T>G p.M4314R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99600310; called by muse, mutect2, varscan2
- DNMT3A | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs1553408222, COSV53056788, COSV99262787; called by muse, mutect2, varscan2
- DNMT3A | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.031); catalogued as COSV99262796; called by muse, mutect2, varscan2
- DNTTIP1 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV65459511; called by muse, mutect2, varscan2
- DOCK3 | c.4506G>A p.V1502= | Splice Region (SNP) | VAF 4/14 reads (29%) | catalogued as rs1204549709, COSV99812736; called by muse, mutect2
- DOP1A | c.4613G>C p.S1538T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.952); catalogued as COSV99382147; called by muse, mutect2, varscan2
- DOP1B | c.4505C>T p.A1502V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200881283, COSV101215489; called by mutect2, varscan2
- DPPA5 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV100951502; called by muse, mutect2
- DPYSL4 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100062683; called by muse, varscan2
- DPYSL4 | c.1381G>T p.V461F | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV100062685; called by muse, varscan2
- DPYSL5 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56512165; called by muse, mutect2, varscan2
- DRD5 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV58581056; called by muse, mutect2, varscan2
- DSCAM | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV101260413; called by muse, mutect2, varscan2
- DST | c.10241C>T p.P3414L | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as COSV99757147; called by muse, mutect2, varscan2
- DST | c.1909C>T p.H637Y (on ENST00000361203 / NM_001374722.1; = p.H311Y on NM_001723.6) | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV99757150; called by muse, mutect2, varscan2
- DUSP10 | c.845A>G p.N282S | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100100594; called by muse, mutect2, varscan2
- DUSP15 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs377341994; called by muse, mutect2, varscan2
- DYNC1LI2 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs756767666, COSV99263064; called by muse, mutect2, varscan2
- DYNC2H1 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518767; called by muse, mutect2, varscan2
- DYNC2I1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs17856461, COSV68107947; called by muse, mutect2, varscan2
- DYRK1B | c.901T>G p.C301G | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100546633; called by muse, mutect2
- DYSF | c.5098C>T p.Q1700* | Nonsense Mutation (SNP) | VAF 11/135 reads (8%) | catalogued as CD1414213, COSV99247804; called by muse, mutect2
- E2F5 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809569, COSV99809589; called by muse, mutect2
- EBF1 | c.802A>G p.S268G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100565547, COSV100565917; called by muse, mutect2, varscan2
- EEA1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100467808; called by muse, mutect2, varscan2
- EEF1A1 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV100303335; called by muse, mutect2, varscan2
- EFCAB5 | c.1907A>C p.Q636P | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100300325; called by muse, mutect2, varscan2
- EGF | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as COSV99491037; called by muse, mutect2, varscan2
- EHMT1 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100603957; called by muse, mutect2, varscan2
- EHMT2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as rs779011466, COSV100977006; called by muse, mutect2, varscan2
- ELFN2 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101297570, COSV68745145; called by muse, mutect2, varscan2
- EMB | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as COSV100296884; called by muse, mutect2, varscan2
- EMILIN1 | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53154992; called by muse, mutect2, varscan2
- EMILIN1 | c.2567G>A p.G856D | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99566276; called by muse, mutect2, varscan2
- EML1 | c.2072C>T p.S691F | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99215140; called by muse, mutect2, varscan2
- ENPP2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV50009888; called by muse, mutect2, varscan2
- EP300 | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV99608842; called by muse, mutect2, varscan2
- EPB41L2 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1263136282, COSV61354929, COSV61358281; called by muse, mutect2, varscan2
- EPB41L4A | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 102/470 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.359); catalogued as COSV99813543; called by muse, varscan2
- EPG5 | c.5531A>T p.Q1844L | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99957458; called by muse, mutect2
- EPG5 | c.5183C>T p.S1728F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99957461; called by muse, mutect2, varscan2
- EPHA4 | c.2299A>G p.M767V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV99916745; called by muse, mutect2, varscan2
- EPHA4 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56028178, COSV56028802; called by muse, mutect2, varscan2
- EPM2AIP1 | c.1543A>G p.N515D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99212494; called by muse, mutect2, varscan2
- EPS8 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV99843266; called by muse, mutect2
- EPX | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138263557; called by muse, mutect2, varscan2
- EPX | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180820614, COSV99836555; called by muse, mutect2, varscan2
- ERBB3 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99917103; called by muse, mutect2, varscan2
- ERC2 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs770952295, COSV99885729; called by muse, mutect2, varscan2
- ERCC2 | c.1897C>T p.L633F | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV101228902; called by muse, mutect2, varscan2
- ERICH3 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs749046982, COSV100444611, COSV58603102; called by muse, mutect2, varscan2
- ERICH3 | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs758715045, COSV100444612; called by muse, mutect2, varscan2
- ERMP1 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV99284567; called by muse, mutect2
- ERN2 | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV99891683; called by muse, mutect2, varscan2
- ESRP1 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100619360; called by muse, mutect2, varscan2
- ETS1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV101200344; called by muse, mutect2
- F10 | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100979226; called by muse, mutect2, varscan2
- F5 | c.3292C>T p.P1098S | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV63121865; called by muse, mutect2, varscan2
- FAF2 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99990511; called by muse, varscan2
- FAM124A | c.834+1G>A p.X278_splice (on ENST00000322475 / NM_001242312.2; = p.X314_splice on NM_145019.4) | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as rs776853177, COSV99696356; called by muse, mutect2, varscan2
- FAM135B | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV52752227; called by muse, mutect2, varscan2
- FAM135B | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1365568888, COSV99424654; called by muse, mutect2, varscan2
- FAM135B | c.1616G>A p.R539K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1461157114, COSV52723837, COSV99419349; called by muse, mutect2, varscan2
- FAM155A | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs759883333, COSV65559809; called by muse, mutect2, varscan2
- FAM166A | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1328746069, COSV100458013; called by muse, mutect2, varscan2
- FAM181A | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as COSV99967906; called by muse, mutect2, varscan2
- FAM227B | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.731); catalogued as COSV100175173; called by muse, mutect2
- FAM234B | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV99545730; called by muse, mutect2, varscan2
- FAM47B | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1438726588, COSV100264382; called by muse, mutect2, varscan2
- FAM78B | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57976080; called by muse, mutect2, varscan2
- FAM81A | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1277100664, COSV99893279; called by muse, mutect2, varscan2
- FAM83C | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as COSV100981592; called by muse, mutect2, varscan2
- FASN | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as COSV100147916, COSV104405069; called by muse, mutect2
- FAT4 | c.13388C>T p.T4463I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as rs199971037, COSV100628879; called by muse, mutect2, varscan2
- FBXL19 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100609039; called by muse, mutect2, varscan2
- FBXL3 | c.711T>G p.S237R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100842364; called by muse, mutect2, varscan2
- FBXO24 | c.365G>A p.R122Q (on ENST00000241071 / NM_033506.3; = p.R160Q on NM_012172.5) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as rs759483658, COSV99575420; called by muse, mutect2, varscan2
- FBXO38 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57029493, COSV57030892; called by muse, mutect2, varscan2
- FCHSD2 | c.1895A>T p.N632I | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV100238570; called by muse, mutect2, varscan2
- FCRL4 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99619941; called by muse, mutect2, varscan2
- FFAR2 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104370321, COSV55832142, COSV99876096; called by muse, mutect2, varscan2
- FGG | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100271920, COSV60194672; called by muse, mutect2, varscan2
- FIGN | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.567); catalogued as COSV100292480; called by muse, mutect2, varscan2
- FILIP1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52734336; called by muse, mutect2, varscan2
- FIP1L1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100184488; called by muse, mutect2
- FLAD1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV99422613; called by muse, mutect2, varscan2
- FLG | c.8438G>A p.G2813E | Missense Mutation (SNP) | VAF 70/689 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV100911646; called by muse, mutect2, varscan2
- FLG2 | c.3416C>T p.S1139F | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.852); catalogued as COSV101165917; called by muse, mutect2, varscan2
- FLI1 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100793658; called by muse, mutect2
- FLI1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857839, COSV99857944; called by muse, mutect2, varscan2
- FLNA | c.2899C>T p.P967S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV100774796; called by muse, mutect2, varscan2
- FLNC | c.1508G>A p.G503D | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1483134760, COSV100368233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.72); PolyPhen probably damaging (1); catalogued as COSV99269169; called by muse, mutect2, varscan2
- FMO3 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs201860024, COSV100882462; called by muse, mutect2, varscan2
- FN1 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.947); catalogued as rs199915234, COSV60563666; called by muse, mutect2
- FN3K | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100333310; called by muse, mutect2, varscan2
- FOXC2 | c.137A>C p.E46A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100234294; called by muse, mutect2, varscan2
- FOXN3 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99726650; called by muse, mutect2, varscan2
- FOXP2 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100646826; called by muse, mutect2, varscan2
- FOXP2 | c.1055G>A p.G352D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100646828; called by muse, mutect2, varscan2
- FOXR2 | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV100189520; called by muse, mutect2, varscan2
- FPR2 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as rs746551181, COSV60673500; called by muse, mutect2, varscan2
- FPR3 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100200765; called by muse, mutect2, varscan2
- FRG2C | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1392290843; called by muse, mutect2, varscan2
- FRY | c.3881A>G p.K1294R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV100969379, COSV66572552; called by muse, mutect2, varscan2
- FRY | c.5465G>A p.S1822N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100969380, COSV66575960; called by muse, mutect2, varscan2
- FSTL4 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV54768385, COSV99532897; called by muse, mutect2, varscan2
- FUBP3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100156170, COSV60515327; called by muse, mutect2, varscan2
- FYB1 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs528139204, COSV100685609; called by muse, mutect2, varscan2
- FZD10 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as COSV57474005, COSV57474138; called by muse, mutect2, varscan2
- G2E3 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV52840920; called by muse, mutect2, varscan2
- GABBR2 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as COSV99410362; called by muse, mutect2
- GABRA6 | c.97A>C p.S33R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV50877852, COSV99194586; called by muse, mutect2, varscan2
- GABRB3 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV100158842; called by muse, mutect2, varscan2
- GABRQ | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs782431029, COSV100941310; called by muse, mutect2, varscan2
- GALP | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs149853638; called by muse, mutect2, varscan2
- GCNT1 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | catalogued as rs367773332; called by muse, mutect2, varscan2
- GCNT1 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as COSV100946575; called by muse, mutect2, varscan2
- GFRA2 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100151738; called by muse, mutect2
- GGA2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100564730; called by muse, mutect2, varscan2
- GGCX | c.693T>A p.Y231* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99289984; called by muse, mutect2, varscan2
- GGN | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99287505; called by muse, mutect2, varscan2
- GH2 | c.592A>C p.K198Q | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100236992; called by muse, mutect2, varscan2
- GHDC | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56989985; called by muse, mutect2, varscan2
- GHR | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50107507; called by muse, mutect2, varscan2
- GJA10 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV101005368; called by muse, mutect2, varscan2
- GLB1 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100257408; called by muse, varscan2
- GLIS2 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV99267620; called by muse, mutect2, varscan2
- GLIS2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV99267622; called by muse, mutect2, varscan2
- GLRA1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774560550, COSV99199571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLRX2 | c.490C>T p.Q164* (on ENST00000367439 / NM_197962.3; = p.Q165* on NM_016066.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as rs763728884, COSV66472187; called by muse, mutect2, varscan2
- GLUD2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV100046724; called by muse, mutect2, varscan2
- GMCL1 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs770452101, COSV99247779; called by muse, mutect2, varscan2
- GMNN | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100017740; called by muse, mutect2, varscan2
- GNAZ | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.322); catalogued as COSV99320859; called by muse, mutect2, varscan2
- GOLGA6A | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1393680956, COSV99297232; called by muse, mutect2, varscan2
- GON4L | c.5293C>T p.H1765Y | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99674596; called by muse, mutect2, varscan2
- GPCPD1 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100980196; called by muse, mutect2
- GPR158 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV100893693; called by muse, mutect2, varscan2
- GPR34 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.222); catalogued as rs1297575396, COSV100587331; called by muse, mutect2, varscan2
- GPR45 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV99307019; called by muse, mutect2, varscan2
- GPR84 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1261153088, COSV99910062; called by muse, mutect2, varscan2
- GPRASP1 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs372366556, COSV64355830; called by muse, mutect2, varscan2
- GPX7 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1331867781, COSV100790945; called by muse, mutect2, varscan2
- GRHL2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99307088; called by muse, mutect2, varscan2
- GRIA1 | c.2659A>G p.M887V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99600371; called by muse, mutect2, varscan2
- GRIA4 | c.1406A>T p.D469V | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99232088; called by muse, mutect2, varscan2
- GRIK1 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV100517045; called by muse, mutect2, varscan2
- GRIK1 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1469312630, COSV100413202; called by muse, mutect2, varscan2
- GRIN2A | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100410118; called by muse, mutect2, varscan2
- GRIN2B | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV74206909; called by muse, mutect2, varscan2
- GRIN2B | c.1540A>C p.T514P | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101663068; called by muse, mutect2, varscan2
- GRIN2C | c.1805C>T p.S602F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99501075; called by muse, mutect2, varscan2
- GRIN3A | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100701563; called by muse, mutect2, varscan2
- GRM1 | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV99266656; called by muse, mutect2, varscan2
- GRM5 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100552401; called by muse, mutect2, varscan2
- GRM8 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100283535, COSV58840174; called by muse, mutect2, varscan2
- GRM8 | c.1265A>T p.D422V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV100283537, COSV58879861; called by muse, varscan2
- GRM8 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283543, COSV58805253; called by muse, varscan2
- GTF3C5 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201326108, COSV100565442; called by muse, mutect2, varscan2
- GTSF1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100007498; called by muse, mutect2
- GUCY2D | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763774686, COSV99079368, COSV99644047; called by muse, mutect2, varscan2
- GUCY2D | c.2602G>A p.G868R | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54697336; called by muse, mutect2, varscan2
- H1-1 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs758141387, COSV99772069; called by muse, mutect2, varscan2
- H2AC17 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV58153478; called by muse, mutect2, varscan2
- H3C3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100778300, COSV63550622; called by muse, mutect2, varscan2
- H3C4 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV100587198, COSV61912486; called by muse, mutect2
- HAS2 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58263652; called by muse, mutect2
- HCFC1 | c.955C>T p.P319S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100129216; called by muse, mutect2, varscan2
- HDAC9 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.621); catalogued as COSV101286810; called by muse, mutect2, varscan2
- HDLBP | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV100190921; called by mutect2, varscan2
- HEATR6 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99482400; called by muse, mutect2, varscan2
- HELZ | c.4465G>A p.G1489R | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV100698795; called by muse, mutect2, varscan2
- HELZ | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.222); catalogued as COSV100698796; called by muse, mutect2, varscan2
- HERC1 | c.10478C>T p.S3493F | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as COSV101496620; called by muse, mutect2, varscan2
- HERC2 | c.5750G>A p.R1917K | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99874408; called by muse, mutect2, varscan2
- HHIP | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV99667353; called by muse, mutect2, varscan2
- HID1 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV100172872; called by muse, mutect2
- HINFP | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV100640857; called by muse, mutect2, varscan2
- HIP1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61192182; called by muse, mutect2, varscan2
- HIP1R | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99458331, COSV99458904; called by muse, mutect2, varscan2
- HIRA | c.2275G>C p.V759L | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV99600475; called by muse, mutect2, varscan2
- HKDC1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV63577266; called by muse, mutect2, varscan2
- HLA-B | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV69521147; called by muse, mutect2, varscan2
- HMCN1 | c.12464G>A p.G4155E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54903366; called by muse, mutect2, varscan2
- HMGCLL1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99232368; called by muse, mutect2, varscan2
- HNRNPCL1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100509014; called by muse, mutect2, varscan2
- HNRNPK | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1370083593, COSV100699032; called by muse, mutect2, varscan2
- HNRNPM | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.166); catalogued as COSV99725623; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1993G>T p.G665C | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99647329; called by muse, mutect2, varscan2
- HOXA3 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.11); catalogued as COSV100415515; called by muse, mutect2, varscan2
- HRNR | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs144088764; called by muse, mutect2, varscan2
- HSD3B7 | c.534C>T p.V178= | Splice Region (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99288167; called by muse, mutect2, varscan2
- HTT | c.8077C>T p.P2693S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767514232, COSV100750865; called by muse, mutect2, varscan2
- HUWE1 | c.7462G>A p.E2488K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99472586, COSV99472729; called by muse, mutect2, varscan2
- HYLS1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99699962; called by muse, mutect2
- IBSP | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs765514286, COSV99883601; called by muse, mutect2, varscan2
- ICA1 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99655411; called by muse, mutect2, varscan2
- IFNAR1 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99531676; called by muse, mutect2, varscan2
- IFRD1 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.615); catalogued as COSV99134023; called by mutect2, varscan2
- IGDCC3 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV60077403; called by muse, mutect2, varscan2
- IGF1R | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV99151653; called by muse, mutect2, varscan2
- IGFBP5 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52082927, COSV52083151; called by muse, mutect2, varscan2
- IGHV1-46 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as rs1555524782; called by muse, mutect2, varscan2
- IGLV3-32 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs144330202; called by muse, mutect2, varscan2
- IGSF1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.091); catalogued as rs1394884588, COSV100812141, COSV63838830; called by muse, varscan2
- IGSF3 | c.3319C>G p.R1107G (on ENST00000369486 / NM_001007237.3; = p.R1127G on NM_001542.4) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.247); catalogued as COSV100604806, COSV59596295; called by muse, mutect2, varscan2
- IL16 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751326013, COSV57261942, COSV57267325; called by muse, mutect2, varscan2
- IL17RA | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100083193; called by muse, mutect2, varscan2
- IL1RAP | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99299802; called by muse, mutect2, varscan2
- IL1RAPL1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100147588; called by muse, mutect2, varscan2
- IL20RB | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV100290891, COSV100291102; called by muse, mutect2, varscan2
- IL2RB | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs776776861, COSV99344975; called by muse, mutect2, varscan2
- IL31RA | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV99763253; called by muse, mutect2, varscan2
- IL6R | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100690860; called by muse, mutect2, varscan2
- IMPG1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV64057554; called by muse, varscan2
- IMPG1 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64057964; called by muse, varscan2
- IMPG2 | c.583+1G>A p.X195_splice | Splice Site (SNP) | VAF 23/74 reads (31%) | catalogued as rs1360618530, COSV99515707; called by muse, mutect2, varscan2
- ING3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV100253328; called by muse, mutect2
- INPP5J | c.1432C>T p.L478F (on ENST00000331075 / NM_001284285.2; = p.L110F on NM_001002837.2) | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as COSV100459512; called by muse, mutect2, varscan2
- IPO9 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.538); catalogued as COSV100843458; called by muse, mutect2, varscan2
- IQCA1 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV99609689; called by muse, mutect2, varscan2
- IQGAP3 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100752178; called by mutect2, varscan2
- IRF5 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs142800920; called by muse, mutect2, varscan2
- ISLR | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV99997370; called by muse, mutect2, varscan2
- ISLR2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.293); catalogued as COSV100679620; called by muse, mutect2, varscan2
- ISM2 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53633683; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- ITFG1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100278858; called by muse, mutect2, varscan2
- ITGAD | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 2/13 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV66758875; called by muse, mutect2
- ITGAD | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs748166194, COSV101210506; called by muse, mutect2, varscan2
- ITGB1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100171727; called by muse, mutect2, varscan2
- ITGB1 | c.485T>G p.V162G | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100171732; called by muse, mutect2, varscan2
- ITGB2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs768468634, COSV100185917; called by muse, mutect2, varscan2
- ITGB3 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71384908; called by muse, mutect2, varscan2
- ITIH3 | c.1657T>C p.Y553H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV101406996; called by muse, mutect2, varscan2
- ITLN1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100406260; called by muse, mutect2
- ITPK1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1313574928, COSV50893873; called by muse, mutect2, varscan2
- ITPKB | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99684576; called by muse, mutect2
- ITPR1 | c.5525C>T p.S1842F (on ENST00000354582; = p.S1787F on NM_002222.7) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100231674; called by muse, mutect2, varscan2
- ITPR1 | c.6839C>T p.S2280L (on ENST00000354582; = p.S2225L on NM_002222.7) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs1379792070, COSV56981900; called by muse, mutect2, varscan2
- ITPR2 | c.2795T>G p.V932G | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV101190021, COSV101190192; called by muse, mutect2, varscan2
- JADE1 | c.865-1G>A p.X289_splice | Splice Site (SNP) | VAF 53/154 reads (34%) | catalogued as COSV99885904; called by muse, mutect2, varscan2
- JAG1 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs934075905, COSV99653033; called by muse, mutect2, varscan2
- JCAD | c.3755G>A p.R1252K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV100948418; called by muse, mutect2, varscan2
- JMJD1C | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs1202972977, COSV101232430; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2366C>T p.T789I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100311620; called by muse, mutect2, varscan2
- JMY | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101268036; called by muse, mutect2, varscan2
- JMY | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.907); catalogued as COSV101268037; called by muse, mutect2, varscan2
- JMY | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.073); catalogued as rs200621350, COSV101268038; called by muse, mutect2, varscan2
- JUNB | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV100040220; called by muse, mutect2, varscan2
- KAT6A | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV99705280; called by muse, mutect2, varscan2
- KATNAL2 | c.1003G>A p.V335I (on ENST00000356157 / NM_001353899.1; = p.V263I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.533); catalogued as rs200886050; called by muse, mutect2, varscan2
- KCNA2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100316009; called by muse, mutect2, varscan2
- KCNC4 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100873594; called by muse, mutect2, varscan2
- KCND2 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100476375, COSV100476653; called by muse, mutect2, varscan2
- KCNG1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857103; called by muse, mutect2, varscan2
- KCNH2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100060245; called by muse, mutect2, varscan2
- KCNK13 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767279149, COSV99965749; called by muse, mutect2, varscan2
- KCNT2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV54106327; called by muse, mutect2
- KCNU1 | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs751762536, COSV67753922; called by muse, mutect2, varscan2
- KCNV2 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101172604; called by muse, mutect2, varscan2
- KERA | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.038); catalogued as COSV57130008, COSV99899478; called by muse, mutect2, varscan2
- KHNYN | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs946780300, COSV99249800; called by muse, mutect2, varscan2
- KIAA2026 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.28); catalogued as rs1377122637, COSV101199082; called by muse, mutect2, varscan2
- KIF21A | c.4585C>T p.L1529F (on ENST00000361418 / NM_001378440.1; = p.L1516F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.359); catalogued as COSV100735493; called by muse, mutect2, varscan2
- KIF21A | c.3051+2T>C p.X1017_splice (on ENST00000361418 / NM_001378440.1; = p.X1004_splice on NM_017641.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 41/127 reads (32%) | catalogued as COSV100735494; called by muse, mutect2, varscan2
- KIF3C | c.1435C>G p.R479G | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as rs1417864146, COSV99267313, COSV99267463; called by muse, mutect2, varscan2
- KIF4B | c.3341G>T p.C1114F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101469303; called by mutect2, varscan2
- KIR2DL3 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 81/407 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as rs755633828; called by muse, mutect2, varscan2
- KIR2DL4 | c.524T>C p.V175A (on ENST00000396284; = p.V136A on NM_001080770.2) | Missense Mutation (SNP) | VAF 109/404 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100610623; called by muse, mutect2, varscan2
- KIR2DL4 | c.797C>T p.S266L (on ENST00000396284; = p.S227L on NM_001080770.2) | Missense Mutation (SNP) | VAF 106/702 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV60879445; called by muse, mutect2, varscan2
- KIRREL2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99384061; called by muse, mutect2, varscan2
- KLF12 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100888529; called by muse, mutect2, varscan2
- KLHDC7A | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1369748561, COSV68769839; called by muse, mutect2, varscan2
- KLHDC8A | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV65679113; called by muse, mutect2, varscan2
- KLHL3 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.081); catalogued as COSV100553303; called by muse, mutect2, varscan2
- KLHL4 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as rs1476085711, COSV64144168; called by muse, mutect2, varscan2
- KLK1 | c.700C>G p.P234A | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100032766; called by muse, varscan2
- KMT2C | c.8275T>G p.Y2759D | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100072742; called by muse, mutect2, varscan2
- KNL1 | c.3011C>T p.S1004F (on ENST00000346991 / NM_170589.5; = p.S978F on NM_144508.5) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV61158397; called by muse, mutect2
- KNL1 | c.5137C>T p.Q1713* (on ENST00000346991 / NM_170589.5; = p.Q1687* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 18/125 reads (14%) | catalogued as COSV100706613; called by muse, mutect2, varscan2
- KNSTRN | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99991886; called by muse, mutect2, varscan2
- KPNA3 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV99904179; called by muse, mutect2, varscan2
- KPNA3 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904180; called by muse, mutect2, varscan2
- KRT14 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.085); catalogued as COSV99391058; called by muse, mutect2, varscan2
- KRT38 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99878253; called by muse, mutect2, varscan2
- KRT40 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66697247; called by muse, mutect2, varscan2
- KRT7 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV99230146; called by muse, mutect2, varscan2
- KRT9 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs201047019, COSV99879245; called by muse, mutect2, varscan2
- KRTAP10-4 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV100554059; called by muse, mutect2, varscan2
- KRTAP12-3 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100554061; called by muse, mutect2, varscan2
- KRTAP19-7 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100603196; called by muse, mutect2, varscan2
- KRTAP20-1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | PolyPhen possibly damaging (0.563); catalogued as rs544292602, COSV100228787; called by muse, mutect2, varscan2
- L3MBTL4 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs768516115, COSV99527432; called by muse, mutect2, varscan2
- LAMA2 | c.7645G>A p.E2549K | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101370530; called by muse, mutect2, varscan2
- LAMA3 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100557004; called by muse, mutect2, varscan2
- LAMB1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as rs1436222151, COSV55961211; called by muse, mutect2, varscan2
- LAMC3 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63095687; called by muse, mutect2, varscan2
- LATS2 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV66873931; called by muse, mutect2, varscan2
- LCK | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100287752; called by muse, mutect2, varscan2
- LCP1 | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59939531; called by muse, mutect2, varscan2
- LELP1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100907348; called by muse, mutect2, varscan2
- LEMD3 | c.2707G>T p.G903C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100384375; called by muse, mutect2, varscan2
- LENG9 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as rs1265724725, COSV100002831; called by muse, mutect2, varscan2
- LEPR | c.33A>T p.L11F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV100756593; called by muse, mutect2, varscan2
- LGR6 | c.589C>T p.R197C (on ENST00000367278 / NM_001017403.1; = p.R145C on NM_021636.3) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866045411, COSV99707189, COSV99707983; called by muse, mutect2, varscan2
- LIFR | c.2921A>C p.Y974S | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104373978, COSV99664440; called by muse, mutect2, varscan2
- LIG3 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.071); catalogued as COSV99252730; called by muse, mutect2, varscan2
- LILRA1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs760878213, COSV52180445; called by muse, mutect2, varscan2
- LILRA2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV52192017; called by muse, mutect2, varscan2
- LILRA4 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99393180; called by muse, mutect2, varscan2
- LILRB5 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100300488; called by muse, mutect2, varscan2
- LOXL4 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53255930; called by muse, mutect2, varscan2
- LRG1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100014899; called by muse, mutect2, varscan2
- LRGUK | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.305); catalogued as rs993242881, COSV99604304; called by muse, mutect2, varscan2
- LRIG3 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100292673; called by muse, mutect2, varscan2
- LRIT3 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59984596; called by muse, mutect2, varscan2
- LRP1B | c.8027T>C p.V2676A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV101257750; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, mutect2, varscan2
- LRP1B | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as rs1015312571, COSV63341598; called by muse, mutect2
- LRP2 | c.9968C>T p.P3323L | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788867; called by muse, mutect2, varscan2
- LRRC10 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.239); catalogued as COSV64060607; called by muse, mutect2, varscan2
- LRRC73 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); catalogued as rs778433778, COSV99446850; called by mutect2, varscan2
- LRRIQ1 | c.3508C>T p.Q1170* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV101280551; called by muse, mutect2, varscan2
- LRRIQ1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 135/425 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV101280552; called by muse, mutect2, varscan2
- LRRIQ4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100540268; called by muse, mutect2, varscan2
- LRRK1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV99440602; called by muse, mutect2, varscan2
- LRRK1 | c.3554T>G p.V1185G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as rs200666835; called by muse, mutect2, varscan2
- LRRK1 | c.5726C>T p.A1909V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV52613988; called by muse, mutect2, varscan2
- LRRK2 | c.5048C>T p.P1683L | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100110433; called by muse, varscan2
- LRRK2 | c.7292G>A p.G2431E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100110435; called by muse, mutect2, varscan2
- LSG1 | c.100T>C p.L34= | Splice Region (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99503300; called by muse, mutect2, varscan2
- LSM14A | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101471707; called by muse, mutect2, varscan2
- LTK | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1467037387, COSV99779052; called by muse, mutect2, varscan2
- LYPD6B | c.541C>T p.P181S (on ENST00000409029 / NM_001317004.1; = p.P205S on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.215); catalogued as rs745526874, COSV54518294; called by muse, mutect2, varscan2
- M1AP | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.68); catalogued as COSV99304179; called by muse, mutect2, varscan2
- MAB21L2 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as COSV100462204; called by muse, mutect2, varscan2
- MAGEB16 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV101303309; called by muse, mutect2, varscan2
- MAGED1 | c.1940T>G p.V647G | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100431632; called by muse, mutect2, varscan2
- MAGED2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99514607; called by muse, mutect2, varscan2
- MAGEL2 | c.2957G>A p.G986E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.141); catalogued as COSV100045988; called by muse, mutect2
- MAGI2 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62653859; called by muse, mutect2, varscan2
- MAL2 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99411042; called by muse, mutect2, varscan2
- MAP1A | c.5487G>A p.M1829I | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV100288755; called by muse, mutect2, varscan2
- MAP1S | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.83); catalogued as rs754821624, COSV60722030; called by muse, varscan2
- MAP2 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV99560387; called by muse, mutect2, varscan2
- MAP3K13 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV53994648; called by muse, mutect2, varscan2
- MAPK10 | c.830A>C p.D277A (on ENST00000359221 / NM_001351625.2; = p.D315A on NM_002753.5) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100174638; called by muse, mutect2, varscan2
- MAPK8IP1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53797747; called by muse, mutect2, varscan2
- MARF1 | c.3568C>T p.Q1190* | Nonsense Mutation (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100706024; called by muse, mutect2, varscan2
- MAS1L | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1366192225, COSV101009699, COSV65809146; called by muse, varscan2
- MASP2 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101280262; called by muse, mutect2, varscan2
- MBD6 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100851691; called by muse, mutect2, varscan2
- MBOAT1 | c.1280G>T p.W427L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100208911; called by muse, varscan2
- MCAM | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as COSV50641565; called by muse, mutect2, varscan2
- MCOLN3 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139077973, COSV62014237; called by muse, mutect2, varscan2
- MDM4 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140091735, COSV100914463; called by muse, mutect2, varscan2
- MDN1 | c.11155C>T p.P3719S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV101021449; called by muse, mutect2, varscan2
- MED1 | c.4342C>T p.P1448S | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100327879, COSV56128385; called by muse, mutect2, varscan2
- MED1 | c.3467C>T p.S1156F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV100327880; called by muse, mutect2, varscan2
- MED12L | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1267220848, COSV99853494; called by muse, mutect2, varscan2
- MED13L | c.2938C>T p.P980S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs1296598446, COSV56125485; called by muse, mutect2, varscan2
- MED30 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1439102801, COSV99816072; called by muse, mutect2, varscan2
- METTL7B | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373097808, COSV99146036; called by muse, mutect2, varscan2
- METTL7B | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57690967; called by muse, mutect2, varscan2
- MFN1 | c.1898G>A p.W633* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV99764502; called by muse, mutect2, varscan2
- MFN1 | c.1899G>A p.W633* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99764505; called by muse, mutect2, varscan2
- MFSD2B | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100601067; called by muse, mutect2, varscan2
- MFSD3 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV100020652; called by muse, mutect2
- MICAL3 | c.5206C>T p.P1736S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.941); catalogued as rs1218583314, COSV101490897; called by muse, mutect2, varscan2
- MIS12 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99342363; called by muse, mutect2, varscan2
- MLLT6 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs770302162; called by mutect2, varscan2
- MMP13 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as rs753779683, COSV99506607; called by muse, mutect2, varscan2
- MMP16 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV99688780; called by muse, mutect2, varscan2
- MMP27 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV99498470; called by muse, mutect2, varscan2
- MMS22L | c.1225T>G p.C409G | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99247101; called by muse, mutect2, varscan2
- MORC2 | c.2836C>T p.P946S (on ENST00000397641 / NM_001303256.3; = p.P884S on NM_014941.3) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99309987; called by muse, mutect2, varscan2
- MOV10 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV53519716; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 27/169 reads (16%) | catalogued as COSV100186873; called by muse, mutect2, varscan2
- MPRIP | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV100505845; called by muse, mutect2, varscan2
- MPZL2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV99635168; called by muse, mutect2, varscan2
- MRAP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57632375; called by muse, mutect2, varscan2
- MROH5 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV101436011; called by muse, mutect2
- MROH8 | c.131G>A p.R44K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV99457416; called by muse, mutect2, varscan2
- MRRF | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV99938918; called by muse, mutect2, varscan2
- MS4A1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as COSV61943281; called by muse, mutect2, varscan2
- MS4A7 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.77); catalogued as COSV100279586; called by muse, mutect2, varscan2
- MSR1 | c.300A>T p.K100N | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV100027443; called by muse, mutect2, varscan2
- MTRF1 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1467465502, COSV99520890; called by muse, mutect2, varscan2
- MTUS2 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101462263; called by muse, mutect2, varscan2
- MUC15 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs779278615, COSV99846480; called by muse, mutect2, varscan2
- MUC16 | c.19386G>A p.W6462* | Nonsense Mutation (SNP) | VAF 40/165 reads (24%) | catalogued as COSV67488299; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC17 | c.2753C>T p.T918I | Missense Mutation (SNP) | VAF 74/861 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.351); catalogued as COSV100073738; called by muse, mutect2
- MUC17 | c.6302G>A p.S2101N | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs746946861, COSV60280647; called by muse, mutect2, varscan2
1,421 further variants in this file (668 protein-altering or splice-affecting, 702 silent, 51 other) are not listed here.
